Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3UW, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3UW-01A (Primary Tumor).

[page 1 of 2]
	6/4/20/12	

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Clinical Diagnosis & History:

History of SCC of tongue. New finding bilateral thyroid nodules FNA positive papillary carcinoma left thyroid nodule.

Specimens Submitted:

1: Thyroid; total thyroidectomy

DIAGNOSIS:

1. Thyroid; total thyroidectomy:

Tumor Type:

Papillary carcinoma, classical type

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Left lobe

Tumor Size:

Greatest diameter is 1.2 cm.

Tumor Encapsulation:

Partially surrounded

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Two foci of papillary microcarcinoma are identified in the isthmus and right lobe, measuring 0.6 cm and 0.3 cm in greatest dimension. The largest microcarcinoma has tall cell features.

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

Exhibits chronic lymphocytic thyroiditis consistent with Hashimoto's thyroiditis

Parathyroid Glands:

Not identified

ICD-O-3

Carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS

CT3A 6-2-12
RD

[page 2 of 2]
Lymph Nodes:

Four benign lymph nodes (0/4).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out *** 1

Gross Description:

1). The specimen is received fresh, labeled "Total thyroid in" and consists of a thyroid weighing 28 grams. The right lobe measures 6.2 x 3.1 x 2.2 cm, the left lobe measures 4.3 x 2.0 x 1.2 cm and the isthmus measures 3.2 x 1.2 x 0.5 cm. A pyramidal lobe is present. It measures 3 x 0.8 x 0.5 cm. There are two lymph nodes identified at the superior aspect of the specimen, each measuring 0.6 x 0.5 cm in greatest dimensions, which are entirely submitted. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a 1.2 x 0.7 x 0.5 cm ill defined firm white-tan nodule in the left lobe, which abuts the capsular surface but does not grossly involve it. A sample of this nodule is given to Sections through the remaining tissue reveal a multi-nodular appearance. The nodules range from soft, brown-tan, and well circumscribed to firm, white-tan, and ill-defined. The largest nodule is located in the right lobe and measures 2.5 x 1.8 x 1.7 cm. The remaining thyroid parenchyma is red tan and meaty. The specimen is completely sectioned at 3 mm intervals and submitted.

Summary of sections:

LN-lymph nodes

RL - right lobe

LL - left lobe

I - isthmus and pyramidal lobe

Summary of Sections:

Part 1: Thyroid; total thyroidectomy

Block	Sect. Site	PCs
5	i	5
10	ll	10
1	ln	1
15	rl	15

Source: NCI Genomic Data Commons file 1cfe4696-7bb9-4a2a-aff8-81d32b5b0363 (TCGA-DJ-A3UW.6DB2037F-9651-4EEB-AFF9-15A23BB19EE4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).